Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6338, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6338-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. RIGHT PELVIC LYMPH NODE
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

TCGA - G9 - 6338

SPECIMEN(S):

- A. RIGHT PELVIC LYMPH NODE
- B. LEFT PELVIC LYMPH NODES
- C. PROSTATE

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

TPA Right pelvic lymph node: Two lymph nodes, negative for tumor.

TPB Left pelvic lymph nodes: Adipose tissue only, no lymph node or tumor identified.

By Dr., called to OR at [REDACTED]

GROSS DESCRIPTION:

A. RIGHT PELVIC LYMPH NODE

Received fresh is a tan-pink fragment of fibrofatty tissue (5 x 2.4 x .5 cm). Dissection reveals two lymph nodes (1 x .6 x .3 cm and 1.2 x .5 x .3 cm). Touch preps are taken and the specimen is submitted in cassettes as follows:

- A1: one lymph node
- A2: one lymph node

B. LEFT PELVIC LYMPH NODES

Received fresh is a tan-pink fragment of fibrofatty tissue (3 x 1 x .5 cm). No lymph node is grossly identified. Touch preps are taken and submitted entirely in cassette in B1.

C. PROSTATE

Received fresh for tissue procurement and labeled with the patient's name designated "prostate", is a resected prostate gland weighing 60 grams and measuring 4.2 cm from right to left, 3.5 cm from apex to base and 9 cm from anterior to posterior. The external capsule is red, smooth and intact. The specimen is inked as follows: apex-red, anterior-orange, base-blue, posterior-black, left-yellow and right-green. Cut section of the specimen shows a tan spongy fibrous tissue. The apex and base are removed from the prostate and the prostate proper weighs 35 grams. The specimen is serially sectioned into levels from apex to base. The right seminal vesicle is 4.7 cm in length with a diameter of 0.3 cm and the left seminal vesicle is 4.1 x 3.5 x 1 cm. The left vas deferens is 3.7 cm in length with a diameter of 0.4 cm and the right seminal vesicle is 4.5 x 1 x 0.5 cm. It is serially sectioned and the vas deferens shows a tan, firm tubular structure. The seminal vesicle has a tan cyst-like tissue. Alternate levels of the specimen are submitted for tissue procurement. The remainder of the prostate gland is submitted for microscopic evaluation. Sections are submitted in toto as follows:

- C1: level I, right anterior
- C2: level I, right posterior
- C3: level I, left anterior
- C4: level I, left posterior
- C5: level II, anterior and right lateral capsule
- C6: level II, posterior and left lateral capsule
- C7: level III, right anterior
- C8: level III, right posterior
- C9: level III, left anterior
- C10: level III, left posterior
- C11: level IV, anterior and right lateral capsule
- C12: level IV, posterior and left lateral capsule
- C13: level V, right anterior
- C14: level V, right posterior
- C15: level V, left anterior
- C16: level V, left posterior
- C17-C18: level VI, capsule, anterior and right lateral
- C19: level VI, capsule, posterior and left lateral
- C20: right apex perpendicularly sectioned
- C21: left apex perpendicularly sectioned
- C22: right mid base perpendicularly sectioned

[page 2 of 2]
C23: left mid base perpendicularly sectioned
C24: right lateral base
C25: left lateral base
C26: root of seminal vesicles and vas deferens
C27: right seminal vesicle and vas deferens
C28: left seminal vesicle and vas deferens

DIAGNOSIS:

- A. LYMPH NODE, RIGHT PELVIC REGION, EXCISION:
- TWO BENIGN LYMPH NODES (0/2)
- B. LYMPH NODE, LEFT PELVIC REGION, EXCISION:
- FIBROADIPOSE TISSUE WITH NO EVIDENCE OF CARCINOMA; NO LYMPH NODES IDENTIFIED.
- C. PROSTATE, PROSTATECTOMY:
- PROSTATIC ADENOCARCINOMA, GLEASON GRADE 4 + 3 = 7/10, INVOLVING RIGHT AND LEFT LOBES OF PROSTATE AND AN ESTIMATED 50% OF GLAND PARENCHYMA.
- ADENOCARCINOMA PRESENT AT LEFT APEX INKED SURFACE (FOCAL, 2 MILLIMETERS).
- PERINEURAL INVASION IDENTIFIED.

SYNOPTIC REPORT - PROSTATE GLAND

Specimens Involved

Specimens: C: PROSTATE

Location: Left

Right

Posterior lateral

Apical

Anterior

WHO CLASSIFICATION

Epithelial tumors

Adenocarcinoma 8140/3

Multicentricity: Yes

Gland Involvement: 50%

Gleason Grade/Sum:: Grade 4 + 3 , Sum 7

High Grade PIN Present: No

Perineural Invasion: Yes

Vascular/Lymphatic Invasion: No

Seminal Vesicle Invasion: No

Periprostatic Fat Involved: Yes

Details: (slide C1) right anterior level 1

Bladder Neck Involved: No

Margins Involvement: Yes

Location: (slide C21) left apex, 2 millimeters

Linear Distance: Focal (1-10mm)

Frozen Performed: No

Post Hormonal Therapy Change: No

Lymph Nodes: Negative Right 0 / 2 Left 0 / 0

Other Pathologic Findings: None identified

Pathological Staging (pTNM): T 3a N 0 M x

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

Prostate carcinoma

Source: NCI Genomic Data Commons file 5ecb6026-8e8f-4273-aa48-b8d7c777249d (TCGA-G9-6338.D3962697-F160-4A76-BFBE-81C06C89D5C3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).